Somatic mutation profile of tumor specimen TCGA-ER-A197-06A (aliquot TCGA-ER-A197-06A-32D-A197-08) from TCGA case TCGA-ER-A197, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.5 years (30,484 days).
Specimen TCGA-ER-A197-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44bbc4e4-ebc7-4553-98f5-57e27cd79d8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A197-10A (Blood Derived Normal), aliquot TCGA-ER-A197-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b72560de-3ac6-40b7-9504-5a90add8a538

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, RNA 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOX1 | c.2231A>C p.H744P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV65982910; called by muse, mutect2, varscan2
- AP3B2 | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55612106; called by muse, mutect2
- BIVM-ERCC5 | c.2050T>C p.S684P | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63246250; called by muse, varscan2
- BRS3 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs750000912, COSV65710797; called by muse, mutect2
- C10orf120 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs745435403, COSV61492339, COSV61492392; called by muse, mutect2, varscan2
- COIL | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV53595853, COSV53596030; called by muse, mutect2, varscan2
- COLEC10 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60522315; called by muse, mutect2, varscan2
- CPLANE1 | c.8665A>G p.T2889A | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV57067732; called by muse, mutect2, varscan2
- GABRA2 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62917188; called by muse, mutect2
- GFOD1 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.611); catalogued as rs753393250, COSV64954627; called by muse, mutect2, varscan2
- HAUS3 | c.33A>T p.L11F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249541649, COSV54721818, COSV54723530; called by muse, mutect2
- IL6 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762371056, COSV51733548; called by muse, mutect2, varscan2
- KIF3A | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66415702; called by muse, mutect2, varscan2
- KLHL11 | c.1910A>T p.E637V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.468); catalogued as COSV59862605; called by muse, mutect2, varscan2
- KLHL13 | c.1192A>G p.S398G | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV53250736; called by muse, mutect2, varscan2
- LIPA | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as rs779697910, COSV51079961; called by muse, mutect2, varscan2
- LMNA | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM070191, COSV61543543; called by muse, mutect2, varscan2
- LRRC1 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746104594, COSV63824666; called by mutect2, varscan2
- MARS1 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV56257163; called by muse, mutect2, varscan2
- MUC3A | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.07); catalogued as COSV100114116; called by muse, mutect2, varscan2
- NEO1 | c.3226C>A p.P1076T | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV56075358; called by muse, mutect2
- NTNG1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as COSV53965263; called by muse, mutect2
- NUP210 | c.1531T>G p.F511V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV54410149; called by muse, mutect2, varscan2
- OR5D18 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV61738028; called by muse, mutect2, varscan2
- OSBPL5 | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV55143855; called by muse, mutect2, varscan2
- PLCL2 | c.1825G>A p.V609M (on ENST00000615277 / NM_001144382.2; = p.V483M on NM_015184.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV67623873; called by muse, mutect2, varscan2
- PSG8 | c.914C>G p.T305R | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV60613778; called by muse, mutect2
- PTPRK | c.3129C>A p.F1043L (on ENST00000368215 / NM_001291984.2; = p.F1044L on NM_002844.4) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV63898234, COSV63903102; called by muse, mutect2, varscan2
- SLC46A3 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs771294912, COSV57183158; called by muse, mutect2, varscan2
- SLC4A4 | c.2405C>T p.T802I (on ENST00000264485 / NM_001098484.3; = p.T758I on NM_003759.4) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52631534; called by muse, mutect2, varscan2
- STS | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54270220; called by muse, mutect2, varscan2
- UNC5D | c.1855A>G p.T619A | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.622); catalogued as rs776287291, COSV54815983, COSV54838829; called by muse, mutect2
- WWOX | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1447332028, COSV68361272; called by muse, mutect2, varscan2
- ZZEF1 | c.2689T>C p.F897L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV67559032; called by muse, mutect2, varscan2
- ADAMTS12 | c.1899T>C p.C633= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV61271075; called by muse, mutect2
- CASP3 | c.549G>A p.A183= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs764966794, COSV57725462; called by muse, mutect2, varscan2
- CDKL1 | c.684A>G p.Q228= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as COSV99367252; called by muse, mutect2, varscan2
- DSCAM | c.2424C>T p.S808= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs777889035, COSV68031960; called by muse, mutect2, varscan2
- EFNB3 | c.829C>T p.L277= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as COSV56834028; called by muse, mutect2, varscan2
- THBD | c.1077C>T p.D359= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV65702899; called by muse, mutect2, varscan2
- TMEM200C | c.441G>A p.T147= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV67309839; called by muse, mutect2, varscan2
- USP18 | c.432C>T p.Y144= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as rs1361428621, COSV53174047; called by muse, mutect2, varscan2
- AC244258.1 | n.894C>A | RNA (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MTMR3 | c.3425+771G>A | Intron (SNP) | VAF 22/105 reads (21%) | catalogued as rs755212804, COSV100070515; called by muse, mutect2, varscan2
